CCDI case PBBWDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3cfc98c9-70f0-4772-91cd-7d27fc3bc628

Demographics
Sex at birth: female.

Diagnoses (1)
1. Astroblastoma: ICD-O-3 morphology code: 9430/3; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 3.6 years (1,313 days).

Biospecimens (3 samples)
- Sample 0DJ6K0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ6KK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DK963: Tissue type: Tumor; Specimen type: Solid Tissue.
